Gene-level copy-number profile of tumor specimen TCGA-D7-8579-01A from TCGA case TCGA-D7-8579, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 66.0 years (24,120 days).
Specimen TCGA-D7-8579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.23a2e88b-9f21-425b-9945-acc93e6bcd72.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-8579-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64a97e92-eeaf-4617-9828-4d60f170502d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 275; copy number 2: 52,541; copy number 3: 6,717; copy number 5: 61; copy number 6: 10; copy number 7: 216.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-8579-01A-11D-2338-01): tumor purity 0.25, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 287 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:34,155,566–34,363,233, 10 genes, copy number 6: AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1.
- chr17:36,634,069–40,598,585, 155 genes, copy number 7 (broad region; genes not listed).
- chr17:59,109,857–60,550,798, 61 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr17:60,677,453–61,392,838, 1 gene, copy number 7 (within-gene range 1–7): BCAS3.
- chr17:60,748,940–61,863,528, 18 genes, copy number 7 (within-gene range 2–7): Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1.
- chr17:65,100,812–67,697,261, 42 genes, copy number 7 (within-gene range 2–7): RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1.

Autosomal genes at a single copy (total copy number 1): 275. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
